Gene-level copy-number profile of specimen HCM-SANG-0548-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0548-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0548-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31c8ce13-bd10-43a0-aa44-eecf946170bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0548-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/bd9f1864-c9c5-4ada-ba6b-f63ec8b27fe0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,824; copy number 2: 13,141; copy number 3: 24,956; copy number 4: 14,668; copy number 5: 964; copy number 6: 275; copy number 7: 281; copy number 8: 152; copy number 10: 89; copy number 13: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 568 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,934,776, 27 genes, copy number 7–8: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5.
- chr19:31,149,979–31,349,436, 1 gene, copy number 7 (within-gene range 5–7): TSHZ3.
- chr19:31,348,881–31,427,302, 3 genes, copy number 7: AC025809.1, AC025809.2, AC008992.1.
- chr19:32,597,006–34,512,304, 59 genes, copy number 7–8: ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP.
- chr19:35,232,291–41,207,539, 326 genes, copy number 7–8 (broad region; genes not listed).
- chr19:42,924,132–42,937,207, 1 gene, copy number 8: PSG7.
- chr19:42,977,463–45,792,845, 151 genes, copy number 8–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,480. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
